Surgical pathology report (de-identified scan), TCGA case TCGA-29-1705, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1705-02A (Recurrent Tumor).

[REDACTED]

Surg Path

CLINICAL HISTORY:

Recurrent ovarian cancer.

GROSS EXAMINATION:

A. "Omentum". Two fragments of adipose tissue (9 x 7 x 2 cm) contain multiple foci of induration up to 1.5 x 1 x 0.5 cm (A1-A2).

B. "Terminal ileum and right colon". A 75 cm long portion of small bowel is received contiguous with a 32 cm long proximal colon. The serosa and adipose tissue contain numerous white-gray plaques from 1 to 10 mm. There are numerous fibrous adhesions and the small bowel is adherent upon itself. The circumference of the small bowel is narrowed at two points from 8 cm to 4 cm. At one of these narrowed points are lodged three oval tan medication pills. There are multiple white-gray submucosal nodules up to 2 cm throughout the entire specimen greater in the small bowel. The entire mucosa is diffusely erythematous and multiple ulcers up to 0.8 cm are identified in the small bowel. At 8.5 cm from the distal end of the colon is an intact colocolonic anastomosis. Multiple large lymph nodes are palpated.

BLOCK SUMMARY:

- B1- tangential proximal margin.
- B2- tangential distal margin.
- B3- serosal plaques.
- B4- small bowel submucosal nodules.
- B5- small bowel adhesion.
- B6- small bowel ulcers.
- B7- ileocecal valve.
- B8- colonic submucosal nodule.
- B9- colonic anastomosis.
- B10 lymph nodes.

ICD-0-3 recurrence

adenocarcinoma, serous, NOS 8441/3

Site: ileum c 17.8 overlapping
with colon

2/12/15
hr

[REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. "OMENTUM":

METASTATIC SEROUS ADENOCARCINOMA, MODERATELY DIFFERENTIATED.

B. "TERMINAL ILEUM AND RIGHT COLON":

METASTATIC SEROUS ADENOCARCINOMA, MODERATELY DIFFERENTIATED.

PROXIMAL MARGIN IS POSITIVE.

MULTIFOCAL ILEAL MUCOSAL ULCER.

MULTIPLE LYMPH NODES, 3 OF 4 INVOLVED

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 15173aaa-38ad-4719-b509-b5218a283f17 (TCGA-29-1705.EADA1E69-0CAB-4521-ABE4-035F73ABB54A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).